CCDI case PBCNDW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/cabff4ea-3a6e-42d5-aac2-4de99dfc611f

Demographics
Sex at birth: female.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Mediastinum, NOS; Age at diagnosis: 0.7 years (262 days).

Biospecimens (2 samples)
- Sample 0DWTAT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWTBN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
